Somatic mutation profile of tumor specimen 0DIKK1 from CCDI case PBBUYX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 2.0 years (747 days).
Specimen 0DIKK1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00499691-8bd3-4b96-8bc0-c66dc83abb4c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIKJE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a822e7e-0bee-4c69-88c0-ccc4f534946a

The open-access MAF lists 6 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, Frame Shift Del 1, Missense Mutation 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GJA5 | c.598del p.R200Gfs*58 | Frame Shift Del (DEL) | VAF 120/332 reads (36%) | catalogued as COSV54784776; called by mutect2, varscan2
- VPS13B | c.5828G>A p.R1943Q | Missense Mutation (SNP) | VAF 55/470 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs904742773, COSV62132994, COSV62150918; called by muse, mutect2, varscan2
- EZHIP | c.129T>G p.A43= | Silent (SNP) | VAF 101/234 reads (43%) | called by muse, mutect2, varscan2
- MYH7B | c.1362C>T p.Y454= | Silent (SNP) | VAF 120/317 reads (38%) | catalogued as rs754743371, COSV53419083; called by muse, mutect2, varscan2
- HERC1 | c.13689-48A>T | Intron (SNP) | VAF 10/55 reads (18%) | called by muse, varscan2
- PRRG4 | c.*62T>C | 3'UTR (SNP) | VAF 16/286 reads (6%) | catalogued as rs1283154682; called by muse, mutect2
